Somatic mutation profile of tumor specimen TCGA-BJ-A0ZA-01A (aliquot TCGA-BJ-A0ZA-01A-11D-A10S-08) from TCGA case TCGA-BJ-A0ZA, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 67.2 years (24,528 days).
Specimen TCGA-BJ-A0ZA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a72f14f-be76-466d-ab9e-89f0b45227d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0ZA-10A (Blood Derived Normal), aliquot TCGA-BJ-A0ZA-10A-02D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da7f7368-e47f-4d3f-abca-a878e3c2e28e

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMOTL1 | c.2099T>G p.F700C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV58568997; called by muse, mutect2
- DHX8 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV52250966, COSV52255335; called by muse, mutect2, varscan2
- DNAH10 | c.11447T>C p.I3816T (on ENST00000409039; = p.I3755T on NM_207437.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as COSV68998480; called by muse, mutect2, varscan2
- FBN2 | c.5950G>A p.V1984M | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs1064796333, COSV52532513, COSV52549529; ClinVar: uncertain significance; called by muse, mutect2
- LPP | c.1430A>G p.N477S | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs951592997, COSV57105712; called by muse, mutect2, varscan2
- PC | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV63081920, COSV63083371; called by muse, mutect2
- TBX5 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1450393334, COSV59863646; called by muse, mutect2, varscan2
- ZRANB3 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV51510171; called by muse, mutect2
- SRPK2 | c.741T>A p.P247= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV61963129; called by muse, mutect2, varscan2
